Gene-level copy-number profile of tumor specimen TCGA-50-6593-01A from TCGA case TCGA-50-6593, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 49.7 years (18,152 days).
Specimen TCGA-50-6593-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9f4afa69-50f4-4049-aa21-b621ca07ed95.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-6593-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/634c3123-1a59-40e5-9115-53f270348b50

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,339; copy number 2: 28,402; copy number 3: 13,443; copy number 4: 12,978; copy number 5: 1,512; copy number 6: 262; copy number 7: 171; copy number 10: 126; copy number 11: 584.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-6593-01A-11D-1752-01): tumor purity 0.31, ploidy 2.94, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,655 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–51,964,445, 734 genes, copy number 5–11 (broad region; genes not listed).
- chr7:35,614,650–50,405,101, 266 genes, copy number 5–7 (broad region; genes not listed).
- chr7:52,891,837–57,275,197, 143 genes, copy number 6 (broad region; genes not listed).
- chr7:115,030,564–120,981,553, 78 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:121,050,927–121,083,813, 2 genes, copy number 5: HMGN1P18, RNA5SP241.
- chr8:55,102,028–55,542,054, 1 gene, copy number 5 (within-gene range 4–5): XKR4.
- chr8:55,449,509–145,066,685, 1,396 genes, copy number 5–7 (broad region; genes not listed).
- chr10:34,815,767–35,231,394, 15 genes, copy number 6: PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P.
- chr21:15,928,296–17,450,104, 20 genes, copy number 6: MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549.

Autosomal genes at a single copy (total copy number 1): 1,645. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
